Somatic mutation profile of tumor specimen C3N-03884-02 (aliquot CPT0237840007) from CPTAC case C3N-03884, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.6 years (23,590 days).
Specimen C3N-03884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80803c9f-7dbc-4e97-b596-2a1fefb99f40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03884-31 (Blood Derived Normal), aliquot CPT0237890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/751d36c8-f678-48e4-a3f1-5e2db158d9eb

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 57/528 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 40/590 reads (7%) | catalogued as rs587784117, CM030072, COSV61786888; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 112/760 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASB16 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 54/435 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs777379847; called by muse, mutect2, varscan2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- COL11A2 | c.3959G>A p.R1320Q (on ENST00000341947 / NM_080680.3; = p.R1213Q on NM_080679.2) | Missense Mutation (SNP) | VAF 64/785 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs372143434; called by muse, mutect2
- CYREN | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs140271713; called by muse, mutect2
- FBN3 | c.7816G>A p.G2606R | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs371456112; called by muse, mutect2, varscan2
- GLI3 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 68/584 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs201047754, COSV67886463; called by muse, mutect2, varscan2
- HHAT | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 45/455 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs770356363; called by muse, mutect2, varscan2
- LAMC3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 154/797 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs773185472, COSV63089505; called by muse, mutect2, varscan2
- RAG1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.474); catalogued as rs147440161, COSV55029145; called by muse, mutect2, varscan2
- RHBDL3 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 103/1196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs749663091; called by muse, mutect2
- SEMA5A | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1440019798; called by muse, mutect2, varscan2
- SF1 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 107/886 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.019); catalogued as rs754963575; called by muse, mutect2, varscan2
- SZT2 | c.6064C>T p.R2022C (on ENST00000634258 / NM_001365999.1; = p.R1965C on NM_015284.4) | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766797004, COSV65174056; called by muse, mutect2, varscan2
- TBC1D9 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 73/786 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV71309321; called by muse, mutect2
- ZNF703 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs1439156854; called by muse, varscan2
- ZNF98 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 53/523 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs759221666, COSV63337859; called by muse, mutect2, varscan2
- BRSK2 | c.1564T>A p.F522I | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BUD31 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 57/557 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- FUCA1 | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 62/603 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAS2 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 120/721 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8H2 | c.470T>A p.F157Y | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- PRR36 | c.3307C>A p.P1103T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2
- TNFRSF12A | c.286T>G p.S96A | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.525); called by muse, mutect2
- WASHC2C | c.2581del p.L861Ffs*11 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | called by mutect2, varscan2
- APBA2 | c.603C>A p.A201= | Silent (SNP) | VAF 136/1211 reads (11%) | called by muse, mutect2, varscan2
- C3orf20 | c.360T>A p.S120= | Silent (SNP) | VAF 64/541 reads (12%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1761C>T p.S587= | Silent (SNP) | VAF 30/586 reads (5%) | catalogued as rs369901419; called by muse, mutect2
- HTR4 | c.1080C>T p.Y360= | Silent (SNP) | VAF 56/433 reads (13%) | called by muse, mutect2, varscan2
- LTA | c.324C>T p.F108= | Silent (SNP) | VAF 64/766 reads (8%) | catalogued as rs372799652; called by muse, mutect2
- MYBPC2 | c.1824G>A p.A608= | Silent (SNP) | VAF 64/683 reads (9%) | catalogued as rs373184181, COSV63093208; called by muse, mutect2
- PCIF1 | c.1389G>A p.R463= | Silent (SNP) | VAF 69/667 reads (10%) | called by muse, mutect2, varscan2
- PRDM13 | c.492C>T p.G164= | Silent (SNP) | VAF 94/806 reads (12%) | catalogued as rs780474604; called by muse, mutect2, varscan2
- YTHDC2 | c.1599C>G p.V533= | Silent (SNP) | VAF 31/315 reads (10%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.480G>T | RNA (SNP) | VAF 21/244 reads (9%) | called by muse, mutect2
